FM case AD2967 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/1050fb6d-8015-439e-9a2b-ccf3c2c5886e

Male, 66.9 years: diagnosis not reported by GDC of the biliary tract; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues of thorax. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
